Somatic mutation profile of tumor specimen TCGA-OR-A5JE-01A (aliquot TCGA-OR-A5JE-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JE, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 17.7 years (6,455 days).
Specimen TCGA-OR-A5JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1c85e1e-dc82-438b-9b88-92b8ca2b2efa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JE-10A (Blood Derived Normal), aliquot TCGA-OR-A5JE-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d1ffda3-9ca2-4d64-9216-68ed1c35d0d2

The open-access MAF lists 60 somatic variants for this specimen: 45 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, Splice Site 4, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, Intron 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as rs1131690884, CM030505, COSV99923959; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.3300+1G>T p.X1100_splice | Splice Site (SNP) | VAF 13/66 reads (20%) | catalogued as rs1458202916; called by muse, mutect2, varscan2
- CHD3 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); catalogued as rs1250977332; called by muse, mutect2, varscan2
- CTNND2 | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs367931998, COSV58893133; called by muse, mutect2, varscan2
- DAXX | c.717_718del p.C240* | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs1423105520; called by mutect2, varscan2
- DENND4B | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100768517; called by muse, mutect2, varscan2
- EDRF1 | c.1160C>T p.P387L (on ENST00000356792 / NM_001202438.2; = p.P353L on NM_015608.2) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61764927; called by muse, mutect2, varscan2
- EYS | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1444000025, COSV60984003; called by muse, mutect2, varscan2
- FBN3 | c.8272G>A p.V2758I | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs773137437; called by muse, mutect2, varscan2
- KMT2B | c.2108G>C p.S703T | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.035); catalogued as COSV52891499; called by muse, mutect2, varscan2
- MEFV | c.1995G>C p.W665C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54827745; called by muse, mutect2, varscan2
- MGMT | c.638G>T p.G213V (on ENST00000306010; = p.G182V on NM_002412.5) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV60026177; called by muse, mutect2, varscan2
- NPAP1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.097); catalogued as COSV61503881; called by muse, mutect2, varscan2
- PRKD1 | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752897300, COSV59576844, COSV59583121; called by muse, mutect2, varscan2
- PRODH2 | c.464C>T p.S155F (on ENST00000301175; = p.S79F on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.915); catalogued as COSV56560991; called by muse, varscan2
- RALGAPA1 | c.2559+1del p.X853_splice | Splice Site (DEL) | VAF 19/128 reads (15%) | catalogued as COSV99354942; called by mutect2, pindel, varscan2
- RBP3 | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140740560; called by muse, mutect2, varscan2
- SEMG1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs770232552, COSV54872445; called by muse, mutect2, varscan2
- SLF2 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.031); catalogued as COSV53273583; called by muse, mutect2, varscan2
- TOP2A | c.3388G>C p.D1130H | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV70733757; called by muse, mutect2, varscan2
- TTN | c.61519G>T p.A20507S (on ENST00000591111; = p.A13083S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | PolyPhen possibly damaging (0.505); catalogued as rs794727433; called by muse, mutect2, varscan2
- CBX8 | c.241_243del p.L81del | In Frame Del (DEL) | VAF 20/100 reads (20%) | called by pindel, varscan2
- CD320 | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- CDC37 | c.191G>T p.C64F | Missense Mutation (SNP) | VAF 39/222 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CELF1 | c.432T>A p.D144E | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by mutect2, varscan2
- COL1A1 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by mutect2, varscan2
- EPHA10 | c.1666G>A p.A556T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHB1 | c.2641A>G p.M881V | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GMPS | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNAS | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO11 | c.1072A>C p.T358P | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NPTX2 | c.644-3_659del p.X215_splice | Splice Site (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- OR5D18 | c.799A>C p.N267H | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PAQR8 | c.594A>C p.K198N | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PSD4 | c.1922_1961del p.X641_splice | Splice Site (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel
- PYGL | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SETDB1 | c.286G>C p.V96L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SH2B1 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STAB2 | c.6585dup p.T2196Hfs*15 | Frame Shift Ins (INS) | VAF 15/110 reads (14%) | called by mutect2, pindel, varscan2
- TEX2 | c.2446G>C p.E816Q (on ENST00000583097 / NM_001288733.2; = p.E823Q on NM_018469.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM63A | c.976C>G p.R326G | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YPEL4 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF45 | c.313T>G p.S105A | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- ZNF701 | c.407A>T p.H136L (on ENST00000301093; = p.H70L on NM_018260.3) | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- ZRANB3 | c.1778C>G p.T593R | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA12 | c.4446C>A p.G1482= (on ENST00000272895 / NM_173076.3; = p.G1164= on NM_015657.3) | Silent (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- C14orf93 | c.1434C>T p.D478= | Silent (SNP) | VAF 42/200 reads (21%) | called by muse, mutect2, varscan2
- CER1 | c.690C>A p.I230= | Silent (SNP) | VAF 33/147 reads (22%) | called by muse, mutect2, varscan2
- FAT3 | c.13608G>A p.V4536= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs955087466; called by muse, mutect2, varscan2
- FCHSD2 | c.1284G>A p.V428= | Silent (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2
- GNAS | c.909T>C p.A303= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as COSV99670191; called by muse, mutect2, varscan2
- JAZF1 | c.405G>A p.E135= | Silent (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- MAN1B1 | c.612A>G p.T204= | Silent (SNP) | VAF 28/115 reads (24%) | called by muse, mutect2, varscan2
- METTL18 | c.765A>G p.P255= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV53683396; called by muse, mutect2, varscan2
- OR14I1 | c.240C>T p.I80= | Silent (SNP) | VAF 87/497 reads (18%) | called by muse, mutect2, varscan2
- OR6F1 | c.171C>A p.T57= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs1411705009; called by muse, mutect2
- PCDHA7 | c.1923C>T p.D641= | Silent (SNP) | VAF 43/211 reads (20%) | catalogued as rs1554135806, COSV65342003; called by muse, mutect2, varscan2
- ZBTB18 | c.534C>T p.A178= | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as rs549802848; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDAC2 | c.-171C>T | 5'UTR (SNP) | VAF 7/40 reads (18%) | catalogued as rs1383442722; called by muse, mutect2, varscan2
- VSTM4 | c.457+3816A>T | Intron (SNP) | VAF 30/130 reads (23%) | called by muse, mutect2, varscan2
